Somatic mutation profile of tumor specimen TCGA-HW-7487-01A (aliquot TCGA-HW-7487-01A-11D-2024-08) from TCGA case TCGA-HW-7487, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.8 years (14,535 days).
Specimen TCGA-HW-7487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f386012b-d3e5-465a-9c38-03edd1371934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7487-10A (Blood Derived Normal), aliquot TCGA-HW-7487-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/964d1f71-ebc8-4eb8-bd35-fb8a33b84663

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380826096, COSV50546987; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/93 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CDKN2C | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52954536; called by muse, mutect2, varscan2
- CHD8 | c.4802G>A p.G1601E (on ENST00000646647 / NM_001170629.2; = p.G1322E on NM_020920.4) | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1392208482, COSV63218970; called by muse, mutect2, varscan2
- FUBP1 | c.1466dup p.Y489* | Nonsense Mutation (INS) | VAF 12/22 reads (55%) | catalogued as COSV53931104; called by mutect2, pindel, varscan2
- IDI1 | c.320T>C p.L107S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67281530; called by muse, mutect2, varscan2
- LAMA3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527373647, COSV58061898; called by muse, mutect2, varscan2
- MISP | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV53119487; called by muse, mutect2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2, varscan2
- SPTBN5 | c.5137C>T p.R1713W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1386332409, COSV58019019; called by muse, mutect2, varscan2
- TRPC7 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1344772983, COSV61453007; called by muse, mutect2, varscan2
- TTN | c.72784G>A p.V24262I (on ENST00000591111; = p.V16838I on NM_003319.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | PolyPhen benign (0.001); catalogued as rs570615498, COSV59896192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.1422C>T p.G474= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs760984970, COSV60912297, COSV60918344; called by muse, mutect2, varscan2
- DAO | c.969C>T p.A323= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs200028465, COSV57321980; called by muse, mutect2, varscan2
- NLRP9 | c.174G>T p.L58= | Silent (SNP) | VAF 192/365 reads (53%) | catalogued as COSV60461723; called by muse, mutect2, varscan2
- TIFAB | c.282G>A p.L94= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as COSV72345753; called by muse, mutect2, varscan2
- UMODL1 | c.1032C>T p.V344= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV61159753; called by muse, mutect2, varscan2
- PHB2 | c.711+172A>G | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs1555151027, COSV99780963; called by muse, mutect2, varscan2
- SSPOP | n.4585C>T | RNA (SNP) | VAF 14/44 reads (32%) | catalogued as rs770055929, COSV50487069; called by muse, mutect2, varscan2
